MMRF case MMRF_2400 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6c2cc90b-022d-495f-9363-0242fd5130eb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.1 years (24,888 days); ISS stage: II; Days to last known disease status: 620 days (1.7 years); Days to last follow up: 620 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 14 days; Days to treatment end: 14 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 2): M Protein 0.7 g/dL; Immunoglobulin G 4.15 g/L; Immunoglobulin A 11.1 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 375 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.
- Day 189 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Immunoglobulin G 3.09 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Glucose 9.9 mmol/L.
- Day 266 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Beta 2 Microglobulin 1.29 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 5.56 mmol/L.
- Day 350 (ECOG 0): Beta 2 Microglobulin 1.62 µg/mL; Hemoglobin 8.12 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 6.77 mmol/L.
- Day 434: Hemoglobin 8.06 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 6.33 mmol/L.
- Day 524 (ECOG 0): Hemoglobin 8.25 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 5.23 mmol/L.
- Day 620 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 7.2 g/L; Immunoglobulin A 1.75 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.24 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -1: Weight: 97 kg; Height: 182 cm.

Biospecimens (2 samples)
- Sample MMRF_2400_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_2400_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
